Gene-level copy-number profile of tumor specimen TCGA-62-A46R-01A from TCGA case TCGA-62-A46R, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 54.9 years (20,063 days).
Specimen TCGA-62-A46R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.e1266195-c743-4671-9357-5917adb8dfb9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-62-A46R-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ee8a55a7-71d0-451c-85cc-b38054c9aee0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,320; copy number 2: 21,368; copy number 3: 5,036; copy number 4: 18,508; copy number 5: 7,725; copy number 6: 5,857.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-62-A46R-01A-11D-A24C-01): tumor purity 0.42, ploidy 2.88, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13,582 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 6 (broad region; genes not listed).
- chr2:85,837,120–242,160,153, 2,750 genes, copy number 5 (broad region; genes not listed).
- chr4:143,559,457–144,343,750, 1 gene, copy number 6 (within-gene range 2–6): AC107223.1.
- chr4:143,577,302–145,958,240, 39 genes, copy number 6 (within-gene range 2–6): FREM3, AC104090.1, GYPE, AC093890.1, GYPB, AC093890.2, GYPA, AC098588.3, AC098588.2, AC106871.1, KRT18P51, HHIP-AS1, HHIP, AC098588.1, ANAPC10, HSPD1P5, AC109811.1, AC109811.2, RN7SKP235, ABCE1, OTUD4, Y_RNA, RPS23P4, LINC02266, RTN3P1, AC079228.1, AC093796.1, NMNAT1P4, SMAD1, SMAD1-AS2, SMAD1-AS1, MMAA, NCOA4P3, AC093864.1, C4orf51, ZNF827, AC104791.2, AC104791.1, Y_RNA.
- chr7:70,972–159,233,377, 3,014 genes, copy number 5–6 (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 6 (broad region; genes not listed).
- chr9:14,475–43,045,120, 776 genes, copy number 5 (broad region; genes not listed).
- chr17:26,989,189–83,095,122, 2,119 genes, copy number 5–6 (broad region; genes not listed).
- chr21:10,328,411–46,665,124, 745 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,320. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
